CCDI case PBCVTA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/e1d7686b-041a-47ac-bbb6-4322570cc8d2

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1BNK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1BNS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1BOB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
